MMRF case MMRF_1277 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a051be7a-9069-408f-91aa-4722524595a1

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 56 years; Vital status: Dead; Days to death: 150 days; Cause of death: Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 56.1 years (20,488 days); ISS stage: III; Days to last known disease status: 150 days; Days to last follow up: 150 days.
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 46 days; Days to treatment end: 77 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 150.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.04 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.3 mg/dL; Immunoglobulin G 1.86 g/L; Immunoglobulin A 45 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 8.95 µg/mL; Hemoglobin 6.76 mmol/L; Leukocytes 7.43 ×10⁹/L; Absolute Neutrophil 4.87 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 11.1 mmol/L; Calcium 3 mmol/L; Albumin 33 g/L; Total Protein 10.8 g/dL; Glucose 16.9 mmol/L.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 36.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 29.4 mg/dL; Immunoglobulin G 5.01 g/L; Immunoglobulin A 3.78 g/L; Immunoglobulin M 0.43 g/L; Beta 2 Microglobulin 5.68 µg/mL; Hemoglobin 6.26 mmol/L; Leukocytes 5.44 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.05 mmol/L; Albumin 35 g/L; Total Protein 6 g/dL; Glucose 11.8 mmol/L.

Other clinical attributes
- Day 1: Weight: 119 kg; Height: 162 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Melanoma; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_1277_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1277_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
